Somatic mutation profile of tumor specimen TCGA-24-1552-01A (aliquot TCGA-24-1552-01A-01W-0551-08) from TCGA case TCGA-24-1552, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 77.0 years (28,129 days).
Specimen TCGA-24-1552-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0e54d53d-b794-4d8c-962a-9b35ad7de2d3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-24-1552-10A (Blood Derived Normal), aliquot TCGA-24-1552-10A-01W-0551-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/167b8db8-ea7e-4204-b27a-dca276b92996

The open-access MAF lists 49 somatic variants for this specimen: 40 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 7, Frame Shift Ins 5, Frame Shift Del 2, Nonsense Mutation 2, In Frame Del 1, 3'UTR 1, Splice Region 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.833C>A p.P278H | Missense Mutation (SNP) | VAF 155/169 reads (92%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs876659802, CM961376, COSV52661225, COSV52665769, COSV52678063; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ACP7 | c.980A>G p.D327G | Missense Mutation (SNP) | VAF 92/3552 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100488497; called by muse, mutect2
- C2orf16 | c.5127_5150del p.R1709_R1716del | In Frame Del (DEL) | VAF 251/679 reads (37%) | catalogued as rs750069300; called by mutect2, varscan2
- COL22A1 | c.4104G>A p.P1368= | Splice Region (SNP) | VAF 18/143 reads (13%) | catalogued as rs769862699, COSV57325231, COSV57342318; called by muse, mutect2
- CRHR1 | c.106G>A p.A36T | Missense Mutation (SNP) | VAF 274/279 reads (98%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV99523562; called by muse, mutect2, varscan2
- D2HGDH | c.1317C>A p.N439K | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100344402; called by muse, mutect2, varscan2
- DLX6 | c.670A>T p.K224* | Nonsense Mutation (SNP) | VAF 120/349 reads (34%) | catalogued as COSV50294903; called by muse, mutect2, varscan2
- DPY19L4 | c.164G>A p.G55D | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68962951, COSV68963144; called by muse, mutect2, varscan2
- DYRK1B | c.394C>G p.Q132E | Missense Mutation (SNP) | VAF 1118/5300 reads (21%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as COSV55682956; called by muse, varscan2
- ELAVL2 | c.1037T>A p.V346E | Missense Mutation (SNP) | VAF 62/144 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.826); catalogued as COSV56363866, COSV56367689; called by muse, mutect2, varscan2
- FNTA | c.157G>T p.D53Y | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV56490342; called by muse, mutect2, varscan2
- FZR1 | c.1124dup p.G376Rfs*4 | Frame Shift Ins (INS) | VAF 4/26 reads (15%) | catalogued as rs1350973455; called by pindel, varscan2
- H2AC8 | c.112G>A p.G38S | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.935); catalogued as rs372540247; called by muse, mutect2, varscan2
- HDAC7 | c.2122G>A p.V708M (on ENST00000427332; = p.V747M on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 115/354 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1425857947, COSV99316146; called by muse, mutect2, varscan2
- HOXA10 | c.469T>C p.C157R | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV52229506; called by muse, mutect2
- MYO18A | c.3194G>C p.R1065P | Missense Mutation (SNP) | VAF 46/51 reads (90%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.511); catalogued as COSV62868298; called by muse, mutect2, varscan2
- NRDE2 | c.2240G>A p.C747Y | Missense Mutation (SNP) | VAF 45/86 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as COSV62963603; called by muse, mutect2, varscan2
- NTHL1 | c.374dup p.V127Gfs*43 (on ENST00000219066; = p.V119Gfs*43 on NM_002528.7 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 12/82 reads (15%) | catalogued as rs763525759; called by mutect2, varscan2
- OR52B6 | c.944G>T p.R315M | Missense Mutation (SNP) | VAF 85/301 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV61447956; called by muse, mutect2, varscan2
- OR7G1 | c.695G>C p.R232T | Missense Mutation (SNP) | VAF 43/151 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as COSV53317954; called by muse, mutect2, varscan2
- PAF1 | c.488T>G p.F163C | Missense Mutation (SNP) | VAF 208/2984 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99655783; called by muse, mutect2
- PPFIBP2 | c.1269del p.T424Lfs*33 | Frame Shift Del (DEL) | VAF 134/596 reads (22%) | catalogued as COSV55081843; called by mutect2, pindel, varscan2
- PPP2R2A | c.1268C>T p.A423V | Missense Mutation (SNP) | VAF 32/60 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.145); catalogued as COSV60097547; called by muse, mutect2, varscan2
- PTBP3 | c.1192G>C p.A398P | Missense Mutation (SNP) | VAF 85/399 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57584058; called by muse, mutect2, varscan2
- PTPRF | c.647G>A p.R216H | Missense Mutation (SNP) | VAF 130/482 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs906834223, COSV63444608; called by muse, mutect2, varscan2
- RBAK | c.150T>G p.D50E | Missense Mutation (SNP) | VAF 225/494 reads (46%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.952); catalogued as COSV62331714; called by muse, mutect2, varscan2
- RINL | c.934G>A p.D312N (on ENST00000591812 / NM_001195833.2; = p.D198N on NM_198445.4) | Missense Mutation (SNP) | VAF 14/438 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.066); catalogued as rs1421900438, COSV100531150; called by muse, mutect2
- RNFT2 | c.1012G>C p.V338L | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV57486382; called by muse, mutect2, varscan2
- SAGE1 | c.1958G>A p.R653H | Missense Mutation (SNP) | VAF 125/146 reads (86%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.806); catalogued as rs139744161, COSV61014370; called by muse, mutect2, varscan2
- SCARF1 | c.1867dup p.A623Gfs*6 | Frame Shift Ins (INS) | VAF 5/31 reads (16%) | catalogued as rs34681910; called by mutect2, pindel, varscan2
- ST18 | c.1205T>C p.I402T | Missense Mutation (SNP) | VAF 221/537 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV52497436; called by muse, mutect2, varscan2
- SYT7 | c.289C>T p.R97W | Missense Mutation (SNP) | VAF 62/161 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.249); catalogued as rs529590239, COSV55655535, COSV99801258; called by muse, mutect2, varscan2
- USO1 | c.469G>T p.V157L | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV53707714; called by muse, mutect2, varscan2
- VWA7 | c.1404C>G p.Y468* | Nonsense Mutation (SNP) | VAF 71/175 reads (41%) | catalogued as COSV65173507; called by muse, mutect2, varscan2
- WDR70 | c.1744G>T p.G582C | Missense Mutation (SNP) | VAF 86/265 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV99458725; called by muse, mutect2, varscan2
- ZNF462 | c.5006G>C p.C1669S | Missense Mutation (SNP) | VAF 33/191 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV52942663; called by muse, mutect2, varscan2
- BRD2 | c.1086dup p.K363* | Frame Shift Ins (INS) | VAF 384/1141 reads (34%) | called by mutect2, pindel, varscan2
- KIF18A | c.483+1del p.X161_splice | Splice Site (DEL) | VAF 24/103 reads (23%) | called by mutect2, pindel, varscan2
- NUMA1 | c.5295dup p.K1766Qfs*38 | Frame Shift Ins (INS) | VAF 8/76 reads (11%) | called by mutect2, varscan2
- SLC23A3 | c.1546_1559del p.L516Rfs*52 (on ENST00000409878 / NM_001144889.2; = p.L399Rfs*52 on NM_144712.5) | Frame Shift Del (DEL) | VAF 36/160 reads (23%) | called by mutect2, pindel, varscan2
- ATP6V1A | c.30C>G p.L10= | Silent (SNP) | VAF 133/929 reads (14%) | catalogued as COSV56362828; called by muse, mutect2, varscan2
- C17orf97 | c.387C>T p.G129= | Silent (SNP) | VAF 54/96 reads (56%) | catalogued as COSV64076745; called by muse, varscan2
- DYRK1B | c.546C>T p.F182= | Silent (SNP) | VAF 335/1408 reads (24%) | catalogued as rs1403212008, COSV59914166; called by mutect2, varscan2
- GABRD | c.1290C>T p.Y430= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as rs774518554, COSV66079949; called by muse, mutect2, varscan2
- GBA | c.969A>G p.Q323= | Silent (SNP) | VAF 399/433 reads (92%) | catalogued as COSV59170085; called by muse, mutect2, varscan2
- LRP3 | c.705C>T p.D235= | Silent (SNP) | VAF 28/81 reads (35%) | catalogued as rs754839310, COSV53504792; called by muse, mutect2, varscan2
- RET | c.2898C>T p.T966= | Silent (SNP) | VAF 21/52 reads (40%) | catalogued as rs373693875; ClinVar: likely benign; called by muse, mutect2, varscan2
- POR | c.*115A>T | 3'UTR (SNP) | VAF 5/12 reads (42%) | catalogued as rs1453339030, COSV58694292; called by muse, mutect2, varscan2
- SNORD115-13 | n.24T>G | RNA (SNP) | VAF 92/232 reads (40%) | called by muse, mutect2, varscan2
